CCDI case PBCSLL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/d89760d8-b104-42ea-9d25-76dcda2f0b3b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Angiomatoid fibrous histiocytoma: ICD-O-3 morphology code: 8836/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 6.2 years (2,271 days).

Biospecimens (2 samples)
- Sample 0E0846: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E084A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
